Somatic mutation profile of tumor specimen TCGA-OR-A5LH-01A (aliquot TCGA-OR-A5LH-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LH, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 36.1 years (13,182 days).
Specimen TCGA-OR-A5LH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddc4714a-5ada-4355-a3aa-6adf9d4ed87e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LH-10A (Blood Derived Normal), aliquot TCGA-OR-A5LH-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5903203a-8ee5-4356-b676-5075474165e2

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Frame Shift Del 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPXM2 | c.1915del p.Q639Rfs*10 | Frame Shift Del (DEL) | VAF 54/98 reads (55%) | catalogued as COSV99582692; called by mutect2, pindel, varscan2
- LRRC36 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 66/93 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52079454; called by muse, mutect2, varscan2
- PRKAR1A | c.1111del p.Q371Sfs*70 | Frame Shift Del (DEL) | VAF 67/120 reads (56%) | catalogued as COSV56837942; called by mutect2, pindel, varscan2
- RASGRF1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 61/104 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs771458045, COSV69179392; called by muse, mutect2, varscan2
- ALG10 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NXPE3 | c.322T>A p.F108I | Missense Mutation (SNP) | VAF 80/100 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PHKA2 | c.1834T>C p.F612L | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PSMC2 | c.136A>C p.K46Q | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- RPN2 | c.915T>G p.V305= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
